Somatic mutation profile of tumor specimen TCGA-C5-A1MP-01A (aliquot TCGA-C5-A1MP-01A-11D-A14W-08) from TCGA case TCGA-C5-A1MP, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 34.7 years (12,692 days).
Specimen TCGA-C5-A1MP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e9f6a37-3ae7-4987-b568-0198be725cfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1MP-10A (Blood Derived Normal), aliquot TCGA-C5-A1MP-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d996071c-a8ca-438b-9d70-fea699700b6b

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS12 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759088490, CM104183, COSV58561034; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTSZ | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413432; called by muse, mutect2
- DALRD3 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58246130, COSV58247362; called by muse, mutect2
- FOXO1 | c.1044C>G p.Y348* | Nonsense Mutation (SNP) | VAF 11/141 reads (8%) | catalogued as COSV101091771; called by muse, mutect2
- GPR153 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147474319, COSV64938117; called by muse, mutect2, varscan2
- GTF2I | c.824G>A p.G275E (on ENST00000573035 / NM_032999.4; = p.G255E on NM_001518.5) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100259441; called by muse, mutect2
- KIF13A | c.619C>G p.R207G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52453220; called by muse, mutect2, varscan2
- L1CAM | c.3500C>T p.P1167L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62827791, COSV62828110; called by muse, mutect2, varscan2
- LRRC59 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV99869357; called by muse, mutect2
- MORC4 | c.2647G>A p.D883N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV99716792; called by muse, mutect2
- PBDC1 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100972781; called by muse, mutect2
- PPP2R5B | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99375835; called by muse, mutect2
- PPP6R3 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs768228824; called by mutect2, varscan2
- RAMP1 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs145088404, COSV99614480; called by muse, mutect2, varscan2
- RHAG | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57703594; called by muse, mutect2, varscan2
- SNX17 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.444); catalogued as rs751854478, COSV99028998; called by muse, mutect2, varscan2
- SON | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as COSV99276848; called by muse, mutect2
- SYNE1 | c.12767T>G p.F4256C (on ENST00000367255 / NM_182961.4; = p.F4185C on NM_033071.3) | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs775066372; called by muse, mutect2, varscan2
- TMEM38A | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV99495115; called by muse, mutect2, varscan2
- UBA52 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV55890688, COSV99723643; called by muse, mutect2, varscan2
- USP20 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs1211954339, COSV59611413; called by muse, mutect2
- ZER1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754228946; called by muse, mutect2, varscan2
- ZNF578 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV69736329; called by muse, mutect2, varscan2
- CENPF | c.8839C>T p.P2947S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CHD1 | c.2851G>T p.G951C | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- DALRD3 | c.854G>C p.C285S (on ENST00000341949 / NM_001009996.3; = p.C118S on NM_018114.5) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- DALRD3 | c.778G>C p.E260Q (on ENST00000341949 / NM_001009996.3; = p.E93Q on NM_018114.5) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAJC14 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLG1 | c.1050+1G>T p.X350_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | called by muse, varscan2
- KCNK16 | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRB2 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ROS1 | c.4802C>T p.A1601V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RPL10 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC47A1 | c.441C>G p.D147E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- SRCAP | c.8341G>A p.V2781I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TGFB3 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- UGT2B17 | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CATSPERB | c.1731G>C p.V577= | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- CCDC71 | c.525C>T p.L175= | Silent (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- CR2 | c.1434C>A p.L478= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV65509438; called by muse, mutect2, varscan2
- ECM1 | c.271C>T p.L91= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100682211; called by muse, mutect2, varscan2
- GPR179 | c.4071G>A p.R1357= (on ENST00000621958; = p.R1356= on NM_001004334.4) | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1356419952; called by muse, mutect2
- PCDH11X | c.1410C>T p.F470= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs768670963, COSV100007108; called by muse, mutect2, varscan2
- PPP2R5B | c.435G>A p.E145= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV51212489; called by muse, mutect2
- PPP6R3 | c.372C>T p.F124= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- RAB10 | c.21C>T p.D7= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- SNX25 | c.204C>T p.L68= | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- TRIM42 | c.711C>T p.L237= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- USH2A | c.1803A>G p.G601= | Silent (SNP) | VAF 34/172 reads (20%) | called by muse, varscan2
- WDR6 | c.2742C>G p.L914= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, varscan2
